Gene-level copy-number profile of tumor specimen TARGET-10-PARVHY-09A from TARGET case TARGET-10-PARVHY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,718 days).
Specimen TARGET-10-PARVHY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.b35a3ae0-9824-5e2f-bad0-097a6c8d4763.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARVHY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 368 have no estimate.
https://portal.gdc.cancer.gov/files/eef0ad99-2928-4318-90b6-dfbe49e25136

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 6; copy number 2: 2,438; copy number 3: 360; copy number 4: 57,103; copy number 5: 150; copy number 6: 62; copy number 8: 97.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr7:142,722,358–142,786,224, 8 genes: PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–2): AC244502.1.
- chr14:22,314,490–22,439,015, 7 genes: TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr17:18,450,244–18,551,705, 7 genes (within-gene range 0–4): KRT16P4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
